Gene-level copy-number profile of tumor specimen HCM-SANG-0278-C20-01A-01D-A80T-32 from HCMI case HCM-SANG-0278-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0278-C20-01A-01D-A80T-32: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0b3b733d-30f7-4142-a4e3-ec210caa7bc6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0278-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/0c5063c7-ee5d-4e85-86b9-c73537cf4802

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 12,561; copy number 2: 39,575; copy number 3: 5,600; copy number 4: 1,130; copy number 5: 6; copy number 7: 20; copy number 9: 1; copy number 10: 7.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–1): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–1): IGHV3-43.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 34 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,526,813–15,994,751, 28 genes, copy number 7–10: DNAJC16, SCARNA21B, AL121992.3, AGMAT, AL121992.1, CHCHD2P6, RNU7-179P, CD24P1, DDI2, RSC1A1, AL121992.2, PLEKHM2, AL450998.2, SLC25A34, SLC25A34-AS1, TMEM82, FBLIM1, RPL12P14, UQCRHL, AL450998.1, FLJ37453, SPEN, AL034555.1, ZBTB17, AL355994.4, AL355994.1, AL355994.5, TBC1D3P6.
- chr2:89,319,625–89,600,680, 3 genes, copy number 5: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr10:38,783,004–38,783,108, 1 gene, copy number 5: AL590623.1.
- chr20:5,750,393–5,864,395, 1 gene, copy number 5: SHLD1.
- chr21:10,649,400–10,649,835, 1 gene, copy number 5: IGHV1OR21-1.

Autosomal genes at a single copy (total copy number 1): 9,815. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
